Somatic mutation profile of tumor specimen TCGA-AK-3427-01A (aliquot TCGA-AK-3427-01A-01D-0966-08) from TCGA case TCGA-AK-3427, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 65.9 years (24,067 days).
Specimen TCGA-AK-3427-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6018c78-1d61-489e-a232-810f496e8728.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3427-10A (Blood Derived Normal), aliquot TCGA-AK-3427-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f888760-e2e2-4396-bc94-a457cec21d90

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHST1 | c.732C>A p.S244R | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs1006152663, COSV57325273, COSV57325431; called by muse, mutect2
- CKAP2L | c.193_195del p.V65del | In Frame Del (DEL) | VAF 79/229 reads (34%) | catalogued as rs1321354894; called by pindel, varscan2
- FGD6 | c.2731C>A p.P911T | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV59696696; called by muse, mutect2, varscan2
- IL1RL2 | c.1242G>C p.E414D | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51815432, COSV51818378; called by muse, mutect2, varscan2
- LAMB1 | c.3266C>G p.A1089G | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV55969608; called by muse, mutect2, varscan2
- MUC17 | c.11538G>T p.L3846F | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV60301274; called by muse, mutect2, varscan2
- SFRP2 | c.883T>G p.C295G | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56838510; called by muse, mutect2, varscan2
- SLC22A6 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs565938595, COSV64560550; called by muse, mutect2, varscan2
- ZNF12 | c.1017C>A p.H339Q (on ENST00000405858 / NM_016265.4; = p.H301Q on NM_006956.3) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.997); catalogued as COSV61245469; called by muse, mutect2, varscan2
- CAPN10 | c.1047C>A p.G349= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as COSV54379474; called by muse, mutect2, varscan2
- FLRT2 | c.838C>A p.R280= | Silent (SNP) | VAF 155/213 reads (73%) | catalogued as COSV58149138; called by muse, mutect2, varscan2
- SYNJ2BP | c.84C>T p.V28= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs763161550, COSV56445467, COSV99832629; called by muse, mutect2, varscan2
- TRNT1 | c.81A>T p.L27= | Silent (SNP) | VAF 43/164 reads (26%) | catalogued as COSV52409391; called by muse, mutect2, varscan2
